Gene-level copy-number profile of tumor specimen TCGA-2G-AAHR-01A from TCGA case TCGA-2G-AAHR, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 38.4 years (14,039 days).
Specimen TCGA-2G-AAHR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7425db27-e7a2-4df7-a1a5-43e1c2a2f515.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAHR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/9dae805f-95a1-4a9a-82fa-78a17de707e0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 780; copy number 2: 21,045; copy number 3: 18,126; copy number 4: 16,746; copy number 5: 2,198; copy number 6: 12.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,632,163–1,737,688, 8 genes (within-gene range 0–2): MMP23B, CDK11B, FO704657.1, SLC35E2B, AL691432.1, MMP23A, CDK11A, AL031282.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,210 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:59,987,269–121,580,524, 1,020 genes, copy number 5 (broad region; genes not listed).
- chr2:151,485,336–229,923,239, 1,178 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr22:25,279,529–25,520,854, 12 genes, copy number 6: AL022332.1, AL022324.4, IGLL3P, AL022324.1, AL022324.2, LRP5L, AL022324.3, AL008721.1, IGLVIVOR22-1, CRYBB2P1, MIR6817, AL008721.2.

Autosomal genes at a single copy (total copy number 1): 268. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
